Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3440, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3440-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Gross Hematuria. CT Revealed Renal Mass Left.

Source of Specimen(s):

- 1: Cartilage left 11th Rib
- 2: Peri renal fat Left Kidney
- 3: Fat Overlying Tumor Left Kidney
- 4: Anterior Upper Pole Lesion
- 5: Anterior Upper Pole Deep Margin
- 6: Anterior Mid Pole Tumor Left Kidney
- 7: Anterior Mid Pole Tumor Deep margin

Gross Description:

Received in seven parts.

Source of Tissue: 1. Labeled #1, "cartilage left 11th rib"

Gross Description: Received fresh labeled "cartilage left 11th rib" is a 3.0 cm in length tan fragment of rib having a minimal amount of attached soft tissue. A representative section is submitted in one block, following decalcification.

Designation of Sections: Block 1

Source of Tissue: 2. Labeled #2, "left perirenal fat kidney"

Gross Description: Received fresh labeled "left perirenal fat kidney" are 237 grams of yellow-tan to pink-red fragments of perinephric fat. They are sectioned to reveal yellow-tan lobulated unremarkable cut surfaces. Representative sections are submitted in three blocks.

Designation of Sections: 2A-2C

Source of Tissue: 3. Labeled #3, "fat overlying tumor left kidney"

Gross Description: Received fresh labeled "fat overlying tumor left kidney" is a 8.5 x 2.5 x 1.0 cm yellow-tan fragment of fibroadipose tissue. It is sectioned to reveal unremarkable cut surfaces. Representative sections are submitted in two blocks.

Designation of Sections: 3A-3B

Source of Tissue: 4. Labeled #4, "anterior upper pole lesion"

Gross Description: Received fresh labeled "anterior upper pole lesion" are 1.0 x 0.8 x 0.3 cm of tan to red-purple irregular soft tissue fragments. They are submitted in toto in one block.

Designation of Sections: Block 4

Source of Tissue: 5. Labeled #5, "anterior upper pole deep margin"

Frozen Section Diagnosis: 5FS- NO TUMOR SEEN PER

Gross Description: Received fresh for frozen section evaluation labeled "anterior upper pole deep margin" is a 0.6 cm tan firm tissue fragment. It is submitted in toto for frozen section evaluation and the frozen itself is submitted in one block.

Designation of Sections: 5FS

[page 2 of 2]
Source of Tissue: 6. Labeled #6, "anterior mid pole tumor left kidney"

Gross Description: Received fresh labeled " [REDACTED] anterior mid pole tumor left kidney" is a 4.5 x 4.0 x 2.5 cm fragment of kidney. It is covered in part by a red-purple capsule. The margin of resection is inked in black, it is sectioned to reveal a 2.5 x 2.5 x 1.8 cm mass having tan-pink soft cut surfaces. Representative sections are submitted in four blocks.

Designation of Sections: 6A-6D

Note: Tissue is submitted for Cytogenetic Studies.

Source of Tissue: 7. Labeled #7, "anterior mid pole tumor deep margin"

Frozen Section Diagnosis: 7FS- BENIGN RENAL TISSUE PER [REDACTED]

Gross Description: Received fresh for frozen section evaluation labeled [REDACTED] anterior mid pole tumor deep margin" is a 0.5 x 0.4 x 0.3 cm tan fragment of soft tissue. It is entirely submitted for frozen section evaluation and the frozen itself is submitted in one block.

Designation of Sections: 7FS

[REDACTED]

Final Diagnosis:

1. Cartilage left 11th rib:

No tumor seen.

2. Left perirenal fat kidney:

No tumor seen.

3. Fat overlying tumor left kidney:

No tumor seen.

4. Anterior upper pole lesion:

No tumor seen.

5. Anterior upper pole deep margin:

No tumor seen.

6. Anterior mid pole tumor left kidney:

Renal cell carcinoma, clear cell (conventional) type, Fuhrman nuclear grade III/IV.

- The 2.5 cm carcinoma is confined to renal parenchyma.

- Angiolymphatic invasion is not identified.

- Surgical resection margins are free of tumor.

7. Anterior mid pole tumor deep margin:

No tumor seen.

pTNM: T1a Nx Mx

Results-Comments

CYTOGENETIC ANALYSIS REPORTS

DIAGNOSIS: Renal Mass

KARYOTYPE: Specimen inadequate for cytogenetic analysis.

RESULTS: Four cultures were established from the renal mass specimen.

After three hours, all four flasks exhibited rampant bacterial contamination. The specimen was not delivered to the cytogenetics laboratory until the next day.

Source: NCI Genomic Data Commons file 2791da99-039c-4d2f-a058-af942da51378 (TCGA-AK-3440.57353F14-2DB0-4DAE-8F64-4AD7959EA765.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).